Somatic mutation profile of tumor specimen TCGA-AR-A24H-01A (aliquot TCGA-AR-A24H-01A-11D-A167-09) from TCGA case TCGA-AR-A24H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.8 years (24,046 days).
Specimen TCGA-AR-A24H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c73a7371-4050-441f-b18f-98d0ec4d22b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24H-10A (Blood Derived Normal), aliquot TCGA-AR-A24H-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a32a11fa-3d87-43af-8086-4015a0acd8b8

The open-access MAF lists 149 somatic variants for this specimen: 120 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 26, Frame Shift Del 9, Nonsense Mutation 5, In Frame Del 5, Splice Site 4, 3'UTR 2, Splice Region 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1B | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs1568670481, CM042491; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2320G>A p.G774S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV55953730; called by muse, mutect2, varscan2
- ABCB7 | c.1392G>T p.Q464H (on ENST00000373394 / NM_001271696.3; = p.Q465H on NM_004299.6) | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53720634; called by muse, mutect2, varscan2
- ABHD16A | c.507G>C p.K169N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as COSV65451931; called by muse, mutect2, varscan2
- AC004593.2 | c.378C>G p.N126K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV56094404; called by muse, mutect2, varscan2
- ACTL6B | c.706A>T p.K236* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV50515668; called by muse, mutect2, varscan2
- ADAMTS17 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1263165889, COSV51483661; called by muse, mutect2, varscan2
- AKAP6 | c.2832G>C p.K944N | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV55217293; called by muse, mutect2, varscan2
- AKNAD1 | c.117T>A p.D39E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as COSV62199475; called by muse, mutect2, varscan2
- AMN | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54486990; called by muse, mutect2
- ANGPTL1 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as COSV52366790; called by muse, mutect2, varscan2
- ANO4 | c.880G>T p.A294S (on ENST00000392977 / NM_001286615.2; = p.A259S on NM_178826.4) | Missense Mutation (SNP) | VAF 199/277 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV54599277; called by muse, mutect2, varscan2
- APOB | c.1697T>C p.M566T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV51939433; called by muse, mutect2, varscan2
- APOB | c.1696A>C p.M566L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV51939448; called by muse, mutect2, varscan2
- ARFGAP2 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as COSV54066374; called by muse, mutect2, varscan2
- ARHGEF11 | c.2803G>T p.G935C | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV100168686; called by muse, mutect2
- ASMTL | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs746554233, COSV67243968; called by muse, mutect2, varscan2
- BIRC6 | c.3097A>G p.T1033A | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV70200859; called by muse, mutect2, varscan2
- C14orf119 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV52977557; called by muse, mutect2, varscan2
- CDKL5 | c.2741G>C p.R914T | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66106735; called by muse, mutect2, varscan2
- CHI3L1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV55138464; called by muse, mutect2, varscan2
- CNOT2 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV57503688; called by muse, mutect2, varscan2
- CSGALNACT2 | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs200474280, COSV65675840; called by muse, mutect2, varscan2
- CXorf21 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV66762798; called by muse, mutect2, varscan2
- DCAF1 | c.4436A>T p.D1479V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV60043763; called by muse, mutect2, varscan2
- DCP1A | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV53689071; called by muse, mutect2, varscan2
- DGUOK | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51203877; called by muse, mutect2, varscan2
- DIAPH2 | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.336); catalogued as COSV61273966; called by muse, mutect2, varscan2
- DKC1 | c.39T>G p.H13Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.048); catalogued as COSV65777380, COSV65777614; called by muse, mutect2, varscan2
- DYNLRB2 | c.6A>C p.A2= | Splice Region (SNP) | VAF 18/27 reads (67%) | catalogued as COSV58416508; called by muse, mutect2, varscan2
- EML1 | c.1816G>T p.G606W | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51746789; called by muse, mutect2, varscan2
- EPB41 | c.197T>A p.L66* | Nonsense Mutation (SNP) | VAF 19/26 reads (73%) | catalogued as COSV58048549; called by muse, mutect2, varscan2
- FCRL4 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV54860343, COSV54863078; called by muse, mutect2, varscan2
- FGD6 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1416061781, COSV59690240; called by muse, mutect2, varscan2
- GPRASP2 | c.1946A>T p.Y649F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as COSV59991634; called by muse, mutect2, varscan2
- GTF3C1 | c.4424G>T p.S1475I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV62241979; called by muse, mutect2, varscan2
- HDAC6 | c.846G>T p.R282S | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0.038); catalogued as COSV61929420; called by muse, mutect2, varscan2
- HMCN1 | c.7733G>A p.S2578N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs373729512; called by muse, mutect2, varscan2
- IGHJ5 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | PolyPhen possibly damaging (0.65); catalogued as rs782688114; called by muse, mutect2, varscan2
- ITGA5 | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as COSV53218482; called by muse, mutect2, varscan2
- ITGB3 | c.1789A>G p.N597D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV71384255; called by muse, mutect2, varscan2
- IVL | c.578T>G p.L193R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100908176; called by muse, mutect2, varscan2
- IVNS1ABP | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV62251311; called by muse, mutect2, varscan2
- LIPE | c.2648G>C p.G883A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV54923414; called by muse, mutect2, varscan2
- LRRC37A3 | c.4270G>C p.E1424Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as COSV100141103; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.1064T>G p.V355G | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV101010830; called by muse, mutect2, varscan2
- MAD2L1BP | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV64665089; called by muse, mutect2, varscan2
- MED7 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53850270; called by muse, mutect2, varscan2
- MSH2 | c.1976A>C p.K659T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51880519; called by muse, mutect2, varscan2
- MYH7 | c.3185C>T p.T1062I | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV62520419; called by muse, mutect2, varscan2
- NAT8L | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59051525; called by muse, mutect2, varscan2
- NOP10 | c.24C>G p.N8K | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV60995515; called by muse, mutect2, varscan2
- NPR2 | c.1557G>A p.L519= | Splice Region (SNP) | VAF 14/78 reads (18%) | catalogued as COSV61311874; called by muse, mutect2, varscan2
- NUPR1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61405089; called by muse, mutect2, varscan2
- NYNRIN | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs773733347, COSV66843087; called by muse, mutect2, varscan2
- OR13J1 | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65069880; called by muse, mutect2, varscan2
- P4HA3 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59041976; called by muse, mutect2, varscan2
- PAX2 | c.992G>A p.R331H (on ENST00000428433 / NM_003987.5; = p.R308H on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs777054297, COSV62291523; called by muse, mutect2, varscan2
- PCDHGA12 | c.1511A>C p.Y504S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99340590; called by muse, mutect2
- PDE4B | c.997del p.E333Kfs*13 | Frame Shift Del (DEL) | VAF 28/46 reads (61%) | catalogued as COSV58481428; called by mutect2, pindel, varscan2
- PIGZ | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs752266694, COSV53013873, COSV53013876; called by muse, mutect2, varscan2
- PIK3R3 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV53108152; called by muse, mutect2, varscan2
- PLEKHA6 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV55335183; called by muse, mutect2, varscan2
- PNPT1 | c.16T>G p.Y6D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV99569985, COSV99570091, COSV99570345; called by muse, mutect2, varscan2
- PPFIBP2 | c.1999-1G>C p.X667_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100206634; called by muse, mutect2, varscan2
- PRKDC | c.2408C>A p.S803* | Nonsense Mutation (SNP) | VAF 38/71 reads (54%) | catalogued as COSV58055162; called by muse, mutect2, varscan2
- PTBP1 | c.1204A>G p.K402E (on ENST00000349038 / NM_031991.4; = p.K428E on NM_002819.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV62460475; called by muse, mutect2
- PUM2 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57582142; called by muse, mutect2, varscan2
- QARS1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs979330776, COSV60275288; called by muse, mutect2, varscan2
- RBM12 | c.1265C>G p.S422* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV58292522; called by muse, mutect2, varscan2
- REV3L | c.4574C>G p.S1525C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62620046; called by muse, mutect2, varscan2
- RFX6 | c.2436C>G p.H812Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.021); catalogued as COSV60586081; called by muse, mutect2, varscan2
- RNF208 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.277); catalogued as COSV61288445; called by muse, mutect2, varscan2
- RPS6KA2 | c.1917C>A p.D639E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55822512; called by muse, mutect2, varscan2
- RYR3 | c.8906A>T p.N2969I (on ENST00000389232; = p.N2970I on NM_001036.6) | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66794620; called by muse, mutect2, varscan2
- SAMD12 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV59051275; called by muse, mutect2, varscan2
- SIGLEC9 | c.458C>A p.T153N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV51585192; called by muse, mutect2, varscan2
- SIX1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs779084301, COSV55960211; called by muse, mutect2, varscan2
- SLC25A39 | c.788G>T p.G263V (on ENST00000377095 / NM_001143780.3; = p.G255V on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV56587753; called by muse, mutect2, varscan2
- SLC38A4 | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV56968374; called by muse, mutect2, varscan2
- SLC39A5 | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV57192118; called by muse, mutect2, varscan2
- SLC7A6 | c.1294T>A p.F432I | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV50450183; called by muse, mutect2, varscan2
- SNRNP70 | c.578-1G>C p.X193_splice | Splice Site (SNP) | VAF 13/16 reads (81%) | catalogued as COSV55505979; called by muse, mutect2, varscan2
- SYNE1 | c.25046T>G p.I8349R (on ENST00000367255 / NM_182961.4; = p.I8301R on NM_033071.3) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV55008755; called by muse, mutect2, varscan2
- SYT17 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs757778066, COSV62546690; called by muse, mutect2, varscan2
- TAF7L | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61257260; called by muse, mutect2, varscan2
- TBX20 | c.1132C>G p.P378A | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV68784066; called by muse, mutect2, varscan2
- TES | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV64042688; called by muse, mutect2, varscan2
- TEX101 | c.187A>T p.T63S (on ENST00000598265 / NM_001130011.3; = p.T81S on NM_031451.4) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.79); PolyPhen benign (0.039); catalogued as COSV53662173, COSV53663419; called by muse, mutect2, varscan2
- TOM1L1 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100779229; called by muse, mutect2
- TRANK1 | c.1945A>G p.T649A | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs770050789, COSV57153415; called by muse, mutect2, varscan2
- TXNDC8 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV65726401; called by muse, mutect2, varscan2
- YEATS2 | c.3841C>A p.Q1281K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV59367110; called by muse, mutect2, varscan2
- ZBTB49 | c.2242A>T p.T748S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61925279; called by muse, mutect2, varscan2
- ZFP64 | c.1082A>C p.H361P | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53800404; called by muse, mutect2, varscan2
- ZFPM2 | c.2066G>C p.C689S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65874183; called by muse, mutect2, varscan2
- ZFYVE28 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373637335, COSV99343797; called by muse, mutect2
- ZNF41 | c.912C>G p.S304R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57443483; called by muse, mutect2, varscan2
- ZNF786 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV60276559; called by muse, mutect2, varscan2
- ZNF830 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV58489684; called by muse, mutect2, varscan2
- ZSWIM2 | c.1260A>T p.K420N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV54574264, COSV54576306; called by muse, mutect2, varscan2
- ASAH2 | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C4BPA | c.143-24_153del p.X48_splice | Splice Site (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- CDH1 | c.2363_2376del p.A788Efs*14 | Frame Shift Del (DEL) | VAF 11/16 reads (69%) | called by mutect2, varscan2
- FAM117A | c.1070_1075del p.G357_P358del | In Frame Del (DEL) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- IGKV1D-33 | c.31_39del p.G11_L13del | In Frame Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, varscan2
- LAMP3 | c.1159_1192del p.I387Vfs*9 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by pindel, varscan2
- MECOM | c.2080_2087del p.F694Pfs*4 (on ENST00000468789 / NM_001105078.4; = p.F882Pfs*4 on NM_004991.4) | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- MRE11 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NAV2 | c.420_432del p.N142* | Frame Shift Del (DEL) | VAF 27/58 reads (47%) | called by mutect2, pindel, varscan2
- NDUFAB1 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- PLEKHA6 | c.2872_2885+22del p.X958_splice | Splice Site (DEL) | VAF 22/140 reads (16%) | called by mutect2, pindel
- PLEKHA6 | c.2710del p.E904Sfs*2 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R12B | c.1776del p.N593Mfs*28 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- PROX1 | c.813_830del p.G272_D277del | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- PTCHD4 | c.1745dup p.P583Afs*9 | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- RAPGEF5 | c.961_969del p.L321_D323del (on ENST00000401957 / NM_001367602.2; = p.L624_D626del on NM_012294.5) | In Frame Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- RHOBTB1 | c.1200_1231del p.R401Sfs*14 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- SLC30A8 | c.869_878del p.L290Qfs*16 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | called by mutect2, pindel, varscan2
- SVEP1 | c.4292_4300del p.E1431_S1433del | In Frame Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- CDK19 | c.1338C>G p.G446= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV60450151; called by muse, mutect2, varscan2
- CHD7 | c.7731G>C p.G2577= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV71111914; called by muse, mutect2, varscan2
- CR2 | c.2346T>A p.S782= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV65508139; called by muse, mutect2, varscan2
- DDX59 | c.1615T>C p.L539= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV58752469; called by muse, mutect2, varscan2
- EGFR | c.594C>T p.S198= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs370376501, COSV51841162; called by muse, mutect2, varscan2
- EHD4 | c.445C>T p.L149= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99588043; called by muse, mutect2, varscan2
- EML1 | c.1815T>C p.T605= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs75430712, COSV51746770; called by muse, mutect2, varscan2
- ERMARD | c.1560T>A p.V520= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV64648242; called by muse, mutect2, varscan2
- ETS1 | c.208C>A p.R70= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100090851; called by muse, mutect2
- FER1L6 | c.3240C>T p.Y1080= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs369965790; called by muse, mutect2, varscan2
- KCNMA1 | c.2997C>T p.I999= (on ENST00000286628 / NM_001161352.2; = p.I941= on NM_002247.4) | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1458348063, COSV54256401; called by muse, mutect2, varscan2
- KIAA1614 | c.816G>T p.L272= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV62552985; called by muse, mutect2, varscan2
- MCMDC2 | c.807A>G p.A269= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV58036877; called by muse, mutect2, varscan2
- MYH8 | c.3990C>T p.N1330= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as rs199830005, COSV67963296; called by muse, mutect2, varscan2
- NUTM2F | c.1074G>C p.L358= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV53558060; called by mutect2, varscan2
- OR5B3 | c.618T>C p.F206= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58677732; called by muse, mutect2, varscan2
- PCDHA12 | c.1026C>T p.D342= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV56513352; called by muse, mutect2, varscan2
- RASSF2 | c.351G>A p.E117= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV65082346; called by muse, mutect2, varscan2
- SNCAIP | c.1431T>A p.V477= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV54412565; called by muse, mutect2, varscan2
- STARD3 | c.192C>T p.I64= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV60420886; called by muse, mutect2, varscan2
- TLR9 | c.2733C>G p.R911= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV62345784, COSV62347210; called by muse, mutect2, varscan2
- TRPM2 | c.681G>C p.L227= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV55971255; called by muse, mutect2, varscan2
- WDFY3 | c.6126G>A p.V2042= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV55703819; called by muse, mutect2, varscan2
- WFIKKN2 | c.108G>A p.P36= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs769127757, COSV60957713; called by mutect2, varscan2
- YWHAG | c.252G>A p.A84= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs569904540, COSV56901364; called by muse, mutect2, varscan2
- ZNF462 | c.2859C>A p.I953= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99472310; called by muse, mutect2
- AC048338.2 | c.*415A>T | 3'UTR (SNP) | VAF 9/14 reads (64%) | catalogued as COSV99928248; called by muse, mutect2, varscan2
- CPLANE1 | c.*4444_*4447delinsCGTGTAAAGA | 3'UTR (INS) | VAF 31/55 reads (56%) | called by pindel, varscan2*
- OFCC1 | n.393-2897A>G | Intron (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
